Somatic mutation profile of tumor specimen HCM-CSHL-0237-C18-01B (aliquot HCM-CSHL-0237-C18-01B-01D-A78L-36) from HCMI case HCM-CSHL-0237-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.3 years (26,416 days).
Specimen HCM-CSHL-0237-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff5acc93-9add-43f7-8631-9a1d173357f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0237-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0237-C18-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a4d1316-154b-4f5f-8245-3c67509671ba

The open-access MAF lists 124 somatic variants for this specimen: 83 protein-altering or splice-affecting, 28 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 28, Intron 6, 3'UTR 4, Splice Site 4, Nonsense Mutation 2, 5'UTR 2, RNA 1, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 111/271 reads (41%) | catalogued as rs1554074738, CM106349, COSV57324862, COSV99966134; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 116/195 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs876660825, CM161004, COSV52664064, COSV52987047, COSV53313892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AAMP | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1311657014, COSV99816538; called by muse, mutect2, varscan2
- APOBEC3C | c.17+2T>C p.X6_splice | Splice Site (SNP) | VAF 31/127 reads (24%) | catalogued as COSV63865125; called by muse, mutect2, varscan2
- ARSG | c.548A>G p.Q183R | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746614421; called by muse, mutect2, varscan2
- BCL11B | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV61735288; called by muse, mutect2, varscan2
- BRIP1 | c.2090C>T p.S697F | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51994743; called by muse, mutect2, varscan2
- C16orf70 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as rs776164057, COSV54625726; called by muse, mutect2, varscan2
- CD5 | c.57C>T p.V19= | Splice Region (SNP) | VAF 33/93 reads (35%) | catalogued as rs923646552; called by muse, mutect2, varscan2
- CFAP20DC | c.2299C>T p.R767C (on ENST00000482387 / NM_001351530.2; = p.R516C on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 136/445 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs772778129, COSV55918830; called by muse, mutect2, varscan2
- CFAP46 | c.3100G>A p.A1034T | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs777460078; called by muse, mutect2, varscan2
- CP | c.2581A>G p.I861V | Missense Mutation (SNP) | VAF 98/309 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.051); catalogued as rs1450174196; called by muse, mutect2, varscan2
- DDX19B | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 55/263 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.13); catalogued as rs772275413; called by muse, mutect2, varscan2
- EFCAB8 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 103/224 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs1224074644; called by muse, mutect2, varscan2
- ELF5 | c.669A>T p.R223S (on ENST00000312319 / NM_198381.2; = p.R213S on NM_001422.4) | Missense Mutation (SNP) | VAF 104/374 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.299); catalogued as COSV56629061; called by muse, mutect2, varscan2
- FLG2 | c.4430G>T p.R1477I | Missense Mutation (SNP) | VAF 162/546 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV66169212; called by muse, mutect2, varscan2
- ISOC1 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.051); catalogued as rs1273700428; called by muse, mutect2, varscan2
- KCNT1 | c.2465A>T p.K822M (on ENST00000488444; = p.K841M on NM_020822.3) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV99706937; called by muse, mutect2, varscan2
- KIF1A | c.3806G>A p.R1269Q (on ENST00000320389 / NM_001379639.1; = p.R1261Q on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs753620726, COSV57502608; called by muse, mutect2, varscan2
- KIF1A | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57488038; called by muse, mutect2, varscan2
- KLHL13 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 151/662 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53246790, COSV99452859; called by muse, mutect2, varscan2
- LHPP | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs140370110, COSV100919331; called by muse, mutect2, varscan2
- LRRC7 | c.2375G>A p.R792H (on ENST00000651989 / NM_001370785.2; = p.R759H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.09); catalogued as rs777755924, COSV50409056, COSV50409162; called by muse, mutect2, varscan2
- MAD1L1 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs771673407, COSV56231308; called by muse, mutect2, varscan2
- MAGEL2 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.06); catalogued as rs1192724337; called by muse, mutect2, varscan2
- MXRA5 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV54234479; called by muse, mutect2, varscan2
- MYORG | c.1933G>C p.E645Q | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs1175104111; called by muse, mutect2, varscan2
- NEUROD2 | c.242dup p.E82Rfs*301 | Frame Shift Ins (INS) | VAF 18/106 reads (17%) | catalogued as rs1428384239; called by mutect2, pindel, varscan2
- PAX5 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 71/333 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV63908493; called by muse, mutect2, varscan2
- PCDHGA2 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); catalogued as rs770680401, COSV53893398, COSV53904096; called by muse, mutect2, varscan2
- PTGFR | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as rs1259928177, COSV66115350; called by muse, mutect2, varscan2
- SART3 | c.1855C>T p.R619W (on ENST00000228284; = p.R601W on NM_014706.4) | Missense Mutation (SNP) | VAF 131/440 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs779251233, COSV57207583; called by muse, mutect2, varscan2
- SCN10A | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 105/357 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs748821446, COSV101479595, COSV71860992; called by muse, mutect2, varscan2
- SCN1A | c.2392A>G p.N798D (on ENST00000303395 / NM_001202435.3; = p.N787D on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV57664136; called by muse, mutect2, varscan2
- SH3RF3 | c.2486G>A p.R829H | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193350267, COSV58685818; called by muse, mutect2, varscan2
- SYNE1 | c.15797C>T p.S5266L (on ENST00000367255 / NM_182961.4; = p.S5195L on NM_033071.3) | Missense Mutation (SNP) | VAF 108/334 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs776756326; called by muse, mutect2, varscan2
- TLE4 | c.2059T>A p.L687M | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776801136; called by muse, mutect2, varscan2
- TNS1 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs377519321; called by muse, mutect2, varscan2
- TRPC5 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 101/199 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1346166663, COSV53303238; called by muse, mutect2, varscan2
- TRPV4 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs387907219, CM118758; called by muse, mutect2, varscan2
- TTF1 | c.2600A>T p.Y867F | Missense Mutation (SNP) | VAF 138/424 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV100524870; called by muse, mutect2, varscan2
- ZNF518B | c.2648G>A p.S883N | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99045076; called by muse, mutect2, varscan2
- BLM | c.145G>T p.V49L | Missense Mutation (SNP) | VAF 67/123 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP128 | c.2960A>T p.D987V | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- DUXB | c.286+1G>C p.X96_splice | Splice Site (SNP) | VAF 73/204 reads (36%) | called by muse, mutect2, varscan2
- FLG | c.4836G>T p.E1612D | Missense Mutation (SNP) | VAF 10/249 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.023); called by muse, mutect2
- FOXE1 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.308); called by muse, mutect2
- FZD6 | c.595A>G p.K199E | Missense Mutation (SNP) | VAF 78/316 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- GATA6 | c.1529del p.N510Ifs*5 | Frame Shift Del (DEL) | VAF 382/719 reads (53%) | called by mutect2, pindel, varscan2
- KCNB2 | c.2409C>A p.S803R | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.115); called by muse, mutect2
- LAMA5 | c.4526G>T p.C1509F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LGI1 | c.1199T>A p.I400N | Missense Mutation (SNP) | VAF 70/446 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MAGEA8 | c.494T>C p.F165S | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEOX2 | c.679A>G p.T227A | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); called by muse, mutect2
- MICU3 | c.485T>C p.F162S | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- NEK10 | c.163A>T p.N55Y | Missense Mutation (SNP) | VAF 117/366 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- NLRP2 | c.1432T>C p.S478P | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- PCDHA11 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- PCDHB14 | c.604T>A p.Y202N | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PCDHGC5 | c.211A>T p.N71Y | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- PDCD11 | c.4208C>T p.P1403L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- PLCE1 | c.266A>T p.K89I | Missense Mutation (SNP) | VAF 144/642 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- RADX | c.2183A>G p.K728R | Missense Mutation (SNP) | VAF 132/284 reads (46%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- RALYL | c.85A>T p.N29Y | Missense Mutation (SNP) | VAF 168/530 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RAVER2 | c.304A>G p.N102D | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.926); called by muse, varscan2
- RPGRIP1L | c.2276A>T p.N759I | Missense Mutation (SNP) | VAF 115/371 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- SEC23A | c.829-1G>A p.X277_splice | Splice Site (SNP) | VAF 56/190 reads (29%) | called by mutect2, varscan2
- SLC7A13 | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC9A7 | c.2178A>G p.*726Wext*16 | Nonstop Mutation (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- SORCS3 | c.2044C>T p.Q682* | Nonsense Mutation (SNP) | VAF 15/118 reads (13%) | called by muse, mutect2, varscan2
- SPATA31A6 | c.3565G>A p.V1189I | Missense Mutation (SNP) | VAF 327/1599 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- TCF21 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THEMIS2 | c.1561G>T p.G521W | Missense Mutation (SNP) | VAF 82/151 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TNNT1 | c.743A>G p.K248R | Missense Mutation (SNP) | VAF 84/326 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRBV30 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2
- TSPYL2 | c.1963G>C p.E655Q | Missense Mutation (SNP) | VAF 119/247 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTC6 | c.62-1G>C p.X21_splice (on ENST00000267368; = p.X1290_splice on NM_001310135.3) | Splice Site (SNP) | VAF 54/176 reads (31%) | called by muse, mutect2, varscan2
- UNC13B | c.1964G>T p.C655F | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- WAS | c.731T>A p.F244Y | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR49 | c.34A>C p.N12H (on ENST00000308378 / NM_001366158.1; = p.N353H on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/418 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNT6 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZAN | c.4094T>C p.F1365S | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF257 | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 81/367 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- FFAR1 | c.198G>A p.A66= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- FOXE1 | c.813G>A p.P271= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- FZD9 | c.717G>A p.S239= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs781942977, COSV100750932; called by muse, mutect2, varscan2
- GFPT2 | c.471C>T p.F157= | Silent (SNP) | VAF 60/246 reads (24%) | catalogued as rs758739868, COSV53807831; called by muse, mutect2, varscan2
- GPR155 | c.1338G>T p.V446= | Silent (SNP) | VAF 41/181 reads (23%) | called by muse, mutect2, varscan2
- HECW1 | c.2295C>T p.G765= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as rs756411752, COSV67835317; called by muse, mutect2, varscan2
- ITGB1 | c.45T>C p.V15= | Silent (SNP) | VAF 43/241 reads (18%) | called by muse, mutect2, varscan2
- LRRC2 | c.118T>C p.L40= | Silent (SNP) | VAF 59/131 reads (45%) | called by muse, mutect2, varscan2
- LRRC37B | c.1644A>G p.P548= | Silent (SNP) | VAF 27/295 reads (9%) | called by muse, mutect2, varscan2
- MAST1 | c.3924C>T p.A1308= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs751536491; called by muse, mutect2, varscan2
- MECOM | c.1017C>G p.P339= (on ENST00000468789 / NM_001105078.4; = p.P527= on NM_004991.4) | Silent (SNP) | VAF 131/462 reads (28%) | catalogued as rs753495560; called by muse, mutect2, varscan2
- MIIP | c.1107G>A p.P369= | Silent (SNP) | VAF 39/63 reads (62%) | catalogued as rs770778672, COSV52428154; called by muse, mutect2, varscan2
- MKX | c.534C>T p.N178= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs973131909, COSV65391761; called by muse, mutect2
- MPDZ | c.3027T>C p.I1009= | Silent (SNP) | VAF 118/574 reads (21%) | called by muse, mutect2, varscan2
- NPAS1 | c.1590G>A p.P530= | Silent (SNP) | VAF 52/130 reads (40%) | catalogued as rs750458086; called by muse, mutect2, varscan2
- OR10AG1 | c.480C>T p.C160= | Silent (SNP) | VAF 54/163 reads (33%) | catalogued as rs754960387, COSV56631269; called by muse, mutect2, varscan2
- PAK3 | c.903A>G p.L301= (on ENST00000262836 / NM_001324328.2; = p.L286= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 122/606 reads (20%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.1947C>T p.H649= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV54057740; called by muse, mutect2, varscan2
- PPIAL4A | c.99G>T p.A33= | Silent (SNP) | VAF 297/849 reads (35%) | called by muse, mutect2, varscan2
- PTPRM | c.2259C>T p.F753= | Silent (SNP) | VAF 136/234 reads (58%) | catalogued as rs749263983, COSV59848593; called by muse, mutect2, varscan2
- SATB1 | c.1314T>C p.A438= | Silent (SNP) | VAF 102/334 reads (31%) | called by muse, mutect2, varscan2
- SHANK1 | c.2190G>T p.V730= | Silent (SNP) | VAF 27/166 reads (16%) | called by muse, mutect2, varscan2
- SND1 | c.2298C>T p.Y766= | Silent (SNP) | VAF 42/160 reads (26%) | catalogued as rs747235161, COSV61235518; called by muse, mutect2, varscan2
- SNED1 | c.2847C>T p.D949= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs368562944; called by muse, mutect2, varscan2
- TCAP | c.333C>A p.I111= | Silent (SNP) | VAF 75/179 reads (42%) | called by muse, mutect2, varscan2
- TMEM183A | c.333T>A p.T111= | Silent (SNP) | VAF 24/137 reads (18%) | catalogued as COSV65887848; called by muse, mutect2, varscan2
- TUB | c.99G>A p.Q33= | Silent (SNP) | VAF 33/197 reads (17%) | called by muse, mutect2, varscan2
- WDR44 | c.403T>C p.L135= | Silent (SNP) | VAF 80/334 reads (24%) | called by muse, mutect2, varscan2
- CDK5RAP1 | c.1248-82A>T | Intron (SNP) | VAF 86/162 reads (53%) | called by muse, mutect2, varscan2
- CNTNAP3P2 | n.1031C>T | RNA (SNP) | VAF 84/432 reads (19%) | catalogued as rs776306183; called by muse, varscan2
- COL6A6 | c.4218+828C>A | Intron (SNP) | VAF 24/234 reads (10%) | catalogued as rs1481666378; called by muse, mutect2, varscan2
- CSHL1 | c.191-17dup | Intron (INS) | VAF 100/395 reads (25%) | catalogued as rs1055509378; called by mutect2, pindel, varscan2
- FGF14 | c.*38G>A | 3'UTR (SNP) | VAF 22/469 reads (5%) | called by muse, mutect2
- JCAD | c.*9C>T | 3'UTR (SNP) | VAF 18/277 reads (6%) | catalogued as rs778939984; called by muse, mutect2
- MLIP | c.64-37866T>C | Intron (SNP) | VAF 92/341 reads (27%) | called by muse, mutect2, varscan2
- OXR1 | c.-1A>T | 5'UTR (SNP) | VAF 75/261 reads (29%) | called by muse, mutect2, varscan2
- RIMS2 | c.177-44376C>T | Intron (SNP) | VAF 175/444 reads (39%) | catalogued as rs767928685; called by muse, mutect2, varscan2
- SEMA5B | c.3091+13G>A | Intron (SNP) | VAF 48/150 reads (32%) | catalogued as rs367763047; called by muse, mutect2, varscan2
- SYNE1 | c.*9G>T | 3'UTR (SNP) | VAF 29/228 reads (13%) | called by muse, mutect2, varscan2
- UFM1 | c.-11C>T | 5'UTR (SNP) | VAF 189/383 reads (49%) | catalogued as rs1241436854; called by muse, mutect2, varscan2
- ZKSCAN5 | c.*931C>T | 3'UTR (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
